Somatic mutation profile of tumor specimen TCGA-Q1-A73Q-01A (aliquot TCGA-Q1-A73Q-01A-21D-A32I-09) from TCGA case TCGA-Q1-A73Q, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage I; Tumor grade: GX; Age at diagnosis: 46.1 years (16,851 days).
Specimen TCGA-Q1-A73Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f37b819-ddf3-43d3-a374-1fc99eed2e39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q1-A73Q-10B (Blood Derived Normal), aliquot TCGA-Q1-A73Q-10B-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/638bd053-cc27-4b82-9e8b-9771ad6974b4

The open-access MAF lists 65 somatic variants for this specimen: 46 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 40, Silent 19, In Frame Del 2, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB2 | c.3458C>T p.S1153L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283190767, COSV57071413; called by muse, mutect2, varscan2
- APEX2 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV66623847; called by muse, mutect2, varscan2
- ARFGEF2 | c.822A>T p.R274S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV64211147; called by muse, mutect2, varscan2
- ARHGAP24 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV67829128, COSV67831975; called by muse, mutect2, varscan2
- AVPI1 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1391074095, COSV101033271; called by muse, mutect2, varscan2
- CCDC39 | c.2017_2019del p.E673del | In Frame Del (DEL) | VAF 35/87 reads (40%) | catalogued as rs780429898; called by pindel, varscan2
- CGB7 | c.384G>T p.L128F | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.06); catalogued as COSV100655035, COSV62281759; called by muse, mutect2, varscan2
- CSMD2 | c.4612G>A p.D1538N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778570107, COSV53880792, COSV53889021; called by muse, mutect2, varscan2
- DDX43 | c.974C>A p.T325N | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64836490; called by muse, mutect2, varscan2
- DDX46 | c.1236G>C p.L412F | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV62798705; called by muse, mutect2, varscan2
- DYNC1H1 | c.6167C>T p.S2056L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64134991; called by muse, mutect2, varscan2
- GSTP1 | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV101282005; called by muse, mutect2
- H3C13 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 163/275 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100516165, COSV58943895, COSV58944644; called by muse, mutect2, varscan2
- HAVCR2 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1266553489, COSV57152055; called by muse, mutect2, varscan2
- IL31RA | c.2086C>A p.P696T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); catalogued as rs905686296, COSV61693036, COSV61697097; called by muse, mutect2, varscan2
- LTBP4 | c.2305G>C p.E769Q (on ENST00000308370 / NM_001042544.1; = p.E732Q on NM_003573.2) | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as COSV52577792; called by muse, mutect2, varscan2
- MAP3K6 | c.3317C>T p.S1106L | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV58870660; called by muse, mutect2, varscan2
- NPC1 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52577011; called by muse, mutect2, varscan2
- PCIF1 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65026166; called by muse, mutect2, varscan2
- PEX12 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs200048804, COSV99862030; called by muse, mutect2, varscan2
- PI3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.046); catalogued as rs142652976; called by muse, mutect2, varscan2
- PLCB1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV62042499; called by muse, mutect2, varscan2
- PRDM9 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs758331193, COSV57003758; called by muse, mutect2, varscan2
- PXYLP1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs142753948; called by muse, mutect2, varscan2
- RAD51AP2 | c.2895G>C p.K965N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV67587555; called by muse, mutect2, varscan2
- RPGRIP1L | c.3236C>T p.S1079L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs777328680, COSV50903296; called by muse, mutect2, varscan2
- RPS6KA6 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV53117292; called by muse, mutect2, varscan2
- RPS6KA6 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV53117304; called by muse, mutect2, varscan2
- SACS | c.8644C>T p.H2882Y | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66536152; called by muse, mutect2, varscan2
- SETD9 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV53649929; called by muse, mutect2, varscan2
- SLC27A1 | c.1469C>G p.S490* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV53095953; called by muse, mutect2, varscan2
- SLC9A1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV56051941; called by muse, mutect2, varscan2
- TAS1R1 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as COSV59839467; called by muse, mutect2, varscan2
- TEP1 | c.6934G>T p.A2312S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV52989374; called by muse, mutect2
- TLR8 | c.2765G>C p.W922S (on ENST00000218032 / NM_138636.5; = p.W940S on NM_016610.4) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54316811; called by muse, mutect2, varscan2
- TMEM132E | c.2164C>A p.H722N (on ENST00000321639; = p.H812N on NM_001304438.2) | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1382193074, COSV58695361, COSV58700899; called by muse, mutect2, varscan2
- VCAN | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.501); catalogued as rs776898982, COSV54099444; called by muse, mutect2, varscan2
- WNK2 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs561344476, COSV52934186; called by muse, mutect2, varscan2
- YEATS2 | c.1024C>G p.Q342E | Missense Mutation (SNP) | VAF 289/313 reads (92%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV59362936; called by muse, mutect2, varscan2
- YEATS2 | c.1097C>G p.S366C | Missense Mutation (SNP) | VAF 380/408 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV59362959; called by muse, mutect2, varscan2
- ZNF557 | c.190G>A p.V64M (on ENST00000414706 / NM_001044388.2; = p.V71M on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs561457120, COSV53273219; called by muse, mutect2, varscan2
- ZNF800 | c.510A>G p.I170M | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56174177; called by muse, mutect2, varscan2
- GRAMD2B | c.959dup p.V322Cfs*13 | Frame Shift Ins (INS) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- NEB | c.10716del p.F3572Lfs*20 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- PRG4 | c.1132_1155del p.P378_T385del | In Frame Del (DEL) | VAF 59/252 reads (23%) | called by mutect2, varscan2
- UBA1 | c.1787_1794del p.L596Rfs*28 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- ABCC12 | c.2613C>T p.F871= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs750264823, COSV60912340; called by muse, mutect2, varscan2
- CCDC80 | c.285G>T p.S95= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV52815511; called by muse, mutect2, varscan2
- CD22 | c.2364G>A p.P788= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs530650512, COSV50050207; called by muse, mutect2, varscan2
- DYNC1H1 | c.6045C>T p.F2015= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV64134987; called by muse, mutect2, varscan2
- EPS8L2 | c.1983C>T p.L661= | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as rs1238981552, COSV59347171; called by muse, mutect2, varscan2
- FARS2 | c.18C>G p.L6= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV51165115, COSV51172845; called by muse, mutect2, varscan2
- FCGBP | c.12000C>A p.S4000= | Silent (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- INPP1 | c.1155G>A p.L385= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV59415195; called by muse, mutect2, varscan2
- MAB21L2 | c.255C>T p.V85= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV58261072; called by muse, mutect2, varscan2
- MAP3K14 | c.1759C>T p.L587= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV60922921, COSV60924788; called by muse, mutect2, varscan2
- MSX1 | c.477G>A p.L159= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV66947080; called by muse, mutect2, varscan2
- NOB1 | c.228C>T p.Y76= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV52061004, COSV52062119; called by muse, mutect2, varscan2
- PRMT8 | c.591C>G p.L197= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV54212247; called by muse, mutect2, varscan2
- PTPRN | c.2619C>T p.L873= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99833694; called by muse, mutect2, varscan2
- SIPA1L3 | c.279G>A p.L93= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV55910371; called by muse, mutect2, varscan2
- SPARCL1 | c.1044C>T p.G348= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs770599706, COSV56802709; called by muse, mutect2, varscan2
- TFAP2C | c.1260G>A p.L420= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV52370695; called by muse, mutect2, varscan2
- THOC2 | c.2709C>T p.V903= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV55542165; called by mutect2, varscan2
- TRAJ38 | c.24G>A p.K8= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs1566731035; called by muse, mutect2, varscan2
